Gene-level copy-number profile of tumor specimen C3N-03015-01 from CPTAC case C3N-03015, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 61.0 years (22,292 days).
Specimen C3N-03015-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 246aca0b-9244-4fd3-9b22-be2cacb9678a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03015-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/e7aee791-f55d-4a5d-a398-bf71ea26a757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 13,898; copy number 2: 40,516; copy number 3: 3,139; copy number 4: 590; copy number 5: 30; copy number 6: 19; copy number 7: 27; copy number 8: 1; copy number 9: 14; copy number 10: 70; copy number 11: 7; copy number 13: 10; copy number 14: 5; copy number 21: 13.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,419,850–120,467,739, 1 gene (within-gene range 0–3): NBPF8.
- chr4:186,286,094–189,475,192, 45 genes (within-gene range 0–2): F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P.
- chr8:4,787,332–4,788,584, 1 gene (within-gene range 0–2): PAICSP4.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr15:30,282,533–30,288,389, 1 gene: AC135731.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 196 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,154,863–68,213,828, 1 gene, copy number 5: KMT5B.
- chr11:68,312,591–68,616,711, 4 genes, copy number 5–8: LRP5, PPP6R3, NDUFA3P2, AP003096.1.
- chr11:69,294,151–71,252,577, 42 genes, copy number 5–21 (within-gene range 2–21): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:70,886,090–70,896,305, 1 gene, copy number 5: AP003783.1.
- chr18:596,988–5,317,664, 97 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr18:21,981,121–24,397,880, 50 genes, copy number 5–13 (within-gene range 2–13): LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1.
- chr18:28,651,732–28,653,208, 1 gene, copy number 7: ARIH2P1.

Autosomal genes at a single copy (total copy number 1): 12,043. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
